Somatic mutation profile of tumor specimen TARGET-30-PAUMBB-01A (aliquot TARGET-30-PAUMBB-01A-01D) from TARGET case TARGET-30-PAUMBB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.3 years (825 days).
Specimen TARGET-30-PAUMBB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d75b5f0-5756-4811-b99b-5e15bdd6ec3d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUMBB-10A (Blood Derived Normal), aliquot TARGET-30-PAUMBB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3905b83-79b2-4448-a2c5-d1ca9c9e39df

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.2757G>A p.G919= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as rs764210072, COSV51686662; called by muse, mutect2, varscan2
- C15orf39 | c.*651G>T | 3'UTR (SNP) | VAF 28/48 reads (58%) | catalogued as COSV62298696; called by muse, mutect2, varscan2
